Surgical pathology report (de-identified scan), TCGA case TCGA-ER-A19D, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site University of Pittsburgh, specimen TCGA-ER-A19D-06A (Metastatic).

100-0-3

Melanoma, NOS 8720/3 12/14/10

PATIENT HISTORY:

No clinical history given.

PRE-OP DIAGNOSIS: Melanoma of back

POST-OP DIAGNOSIS: Same

PROCEDURE: Right wide excision melanoma of back, sentinel node biopsy

Site code: Subcutaneous tissue C49.3

**FINAL DIAGNOSIS:**

PART 1: SOFT TISSUE, CHEST WALL, DEEP MARGIN -

FIBROADIPOSE TISSUE, NEGATIVE FOR MALIGNANCY.

PART 2: SENTINEL LYMPH NODE #1, RIGHT AXILLARY, EXCISION -

ONE (1) BENIGN LYMPH NODE, NEGATIVE FOR MALIGNANCY (see comment).

PART 3: SENTINEL LYMPH NODE #2, RIGHT AXILLARY, EXCISION -

ONE (1) BENIGN LYMPH NODE, NEGATIVE FOR MALIGNANCY (see comment).

PART 4: SENTINEL LYMPH NODE #3, RIGHT AXILLARY, EXCISION -

ONE (1) BENIGN LYMPH NODE, NEGATIVE FOR MALIGNANCY.

PART 5: SENTINEL LYMPH NODE #4, RIGHT AXILLARY, EXCISION -

ONE (1) BENIGN LYMPH NODE, NEGATIVE FOR MALIGNANCY (see comment).

PART 6: NON-SENTINEL LYMPH NODE, RIGHT AXILLARY, EXCISION -

ONE (1) BENIGN LYMPH NODE, NEGATIVE FOR MALIGNANCY.

PART 7: SENTINEL LYMPH NODE #5, RIGHT AXILLARY, EXCISION -

ONE (1) BENIGN LYMPH NODE, NEGATIVE FOR MALIGNANCY.

PART 8: SKIN AND SOFT TISSUE, CHEST WALL, WIDE EXCISION -

A. METASTATIC MELANOMA IN SUBCUTANEOUS SOFT TISSUE (see comment).

B. TUMOR INVOLVES MARGINS OF EXCISION.

C. SKIN WITH SCAR AND FOREIGN-BODY GIANT-CELL REACTION.

COMMENT:

Immunostains were performed on the sentinel lymph nodes #1, 2 and 4 (parts 2, 3 and 5). Dendritic cells are highlighted by S100 and macrophages are decorated by CD68. Immunostains for melanA, tyrosinase and HMB45 are negative. A CD31 immunostain on part 5 shows the vasculature. The tumor in part 8 is immunoreactive for S100 and negative for melanA, tyrosinase and cytokeratin (AE1/3), supporting melanoma.

Source: NCI Genomic Data Commons file d89bc221-8683-4a11-b0c8-5b09f18c0742 (TCGA-ER-A19D.20CEC313-3D84-4D2D-B229-1AF7CCF4354C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).